Somatic mutation profile of tumor specimen TCGA-GN-A264-06A (aliquot TCGA-GN-A264-06A-11D-A196-08) from TCGA case TCGA-GN-A264, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 68.1 years (24,888 days).
Specimen TCGA-GN-A264-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30ba9bfd-c34c-4058-955e-7176cd56bf76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A264-10A (Blood Derived Normal), aliquot TCGA-GN-A264-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96251801-1290-4465-94b1-0d24841681a6

The open-access MAF lists 47 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 30, Silent 11, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2466T>G p.N822K | Missense Mutation (SNP) | VAF 106/167 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913514, COSV55387147, COSV55389584, COSV55431266; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD44 | c.739T>C p.C247R | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56551591; called by muse, mutect2, varscan2
- ARID5B | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0.024); catalogued as COSV54416850; called by muse, mutect2, varscan2
- BBS7 | c.1154T>G p.F385C | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV52655411; called by muse, mutect2, varscan2
- BMS1 | c.3046G>A p.D1016N | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.739); catalogued as COSV65733273; called by muse, mutect2, varscan2
- BRINP3 | c.1653G>T p.L551F | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV66517835; called by muse, mutect2, varscan2
- BRPF1 | c.686A>T p.N229I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57403955; called by muse, varscan2
- CBFA2T2 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV60073503; called by muse, mutect2, varscan2
- CTU2 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV56335165; called by muse, mutect2, varscan2
- DPEP2 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52054132; called by muse, varscan2
- DYNC1H1 | c.2888G>C p.R963T | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.201); catalogued as COSV64135338; called by muse, mutect2, varscan2
- GRIN3A | c.1433G>T p.W478L | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62452041, COSV62458083; called by muse, mutect2, varscan2
- IL6ST | c.1516A>C p.S506R | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV61140511; called by muse, mutect2, varscan2
- IQGAP3 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs188149873, COSV63250301; called by muse, varscan2
- LPCAT1 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs747860604, COSV52036505; called by mutect2, varscan2
- LRRC4 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50813468; called by muse, mutect2, varscan2
- NID1 | c.3483G>T p.K1161N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs758809303, COSV51617563, COSV51619369; called by muse, mutect2, varscan2
- PRDM9 | c.630C>A p.N210K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV57004303, COSV57007878; called by muse, mutect2, varscan2
- PTPRT | c.2350G>T p.A784S | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as COSV61970276; called by muse, mutect2, varscan2
- RBKS | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as rs753654813, COSV56221039; called by muse, mutect2, varscan2
- TIMM21 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV50053374, COSV50053463; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1240-1G>A p.X414_splice | Splice Site (SNP) | VAF 16/120 reads (13%) | catalogued as rs373723111, COSV54648721; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV54648725; called by mutect2, varscan2
- TSNAXIP1 | c.1687G>T p.E563* | Nonsense Mutation (SNP) | VAF 25/171 reads (15%) | catalogued as COSV54648730; called by muse, mutect2, varscan2
- WWP2 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.038); catalogued as rs1473094766, COSV100598592, COSV63124040; called by muse, mutect2, varscan2
- YBX1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs141968223, COSV58439712; called by muse, mutect2, varscan2
- YTHDC1 | c.1447G>C p.E483Q (on ENST00000344157 / NM_001031732.4; = p.E465Q on NM_133370.4) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.645); catalogued as COSV60009446, COSV60010705; called by muse, mutect2, varscan2
- ZNF16 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs371831481; called by muse, mutect2, varscan2
- ZNF208 | c.859T>A p.C287S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68102818; called by muse, mutect2, varscan2
- ZNF408 | c.893G>C p.G298A | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV61237807; called by muse, mutect2, varscan2
- ARCN1 | c.684del p.G229Efs*7 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- HNRNPA2B1 | c.300+1_300+5del p.X100_splice (on ENST00000354667 / NM_031243.3; = p.X88_splice on NM_002137.4) | Splice Site (DEL) | VAF 94/289 reads (33%) | called by mutect2, pindel, varscan2
- MCUB | c.386T>A p.L129* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- NAALADL2 | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- OR5D14 | c.110_113del p.Y37Lfs*5 | Frame Shift Del (DEL) | VAF 28/44 reads (64%) | called by pindel, varscan2
- TTN | c.102049A>G p.S34017G (on ENST00000591111; = p.S26593G on NM_003319.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | PolyPhen benign (0.053); called by mutect2, varscan2
- ACER1 | c.516G>A p.L172= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV56835047; called by muse, mutect2, varscan2
- COX11 | c.69G>T p.G23= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as COSV54802640; called by muse, mutect2, varscan2
- DDIT3 | c.15A>C p.S5= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV56253451; called by muse, mutect2, varscan2
- ESF1 | c.2373G>A p.E791= | Silent (SNP) | VAF 29/182 reads (16%) | catalogued as rs1264076784, COSV52519937; called by muse, mutect2, varscan2
- LRRN1 | c.1326G>A p.T442= | Silent (SNP) | VAF 70/103 reads (68%) | catalogued as rs1455331112, COSV60013119; called by muse, mutect2, varscan2
- NOMO2 | c.1095C>T p.F365= | Silent (SNP) | VAF 51/111 reads (46%) | catalogued as COSV57916153; called by muse, mutect2, varscan2
- PCDHA7 | c.969C>T p.V323= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs782793159, COSV65343103; called by muse, mutect2, varscan2
- POU1F1 | c.828G>A p.L276= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs757553541, COSV55461605; called by muse, mutect2, varscan2
- TIAM1 | c.4242T>C p.Y1414= | Silent (SNP) | VAF 39/69 reads (57%) | catalogued as COSV54543269; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1080G>A p.G360= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs749917081, COSV54648974; called by muse, mutect2, varscan2
- WNK4 | c.3213T>G p.A1071= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV55902736; called by muse, mutect2, varscan2
